Somatic mutation profile of tumor specimen TCGA-24-1435-01A (aliquot TCGA-24-1435-01A-01W-0549-09) from TCGA case TCGA-24-1435, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.8 years (21,107 days).
Specimen TCGA-24-1435-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fad8bf9-dec6-44c6-9732-bccba0e6902b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1435-10A (Blood Derived Normal), aliquot TCGA-24-1435-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbd9913c-a7dc-496e-9861-1752dc53889f

The open-access MAF lists 110 somatic variants for this specimen: 88 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 18, Frame Shift Del 6, Intron 4, Nonsense Mutation 2, Splice Site 2, In Frame Del 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIGO | c.2361dup p.T788Hfs*5 | Frame Shift Ins (INS) | VAF 14/114 reads (12%) | catalogued as rs770591449; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 76/125 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHCTF1 | c.680G>C p.G227A (on ENST00000366508; = p.G201A on NM_015446.5) | Missense Mutation (SNP) | VAF 59/72 reads (82%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); catalogued as COSV58247633; called by muse, mutect2, varscan2
- APOB | c.4580T>A p.L1527H | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51928977; called by muse, mutect2, varscan2
- ARHGAP5 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as rs771966068, COSV61534587; called by muse, mutect2, varscan2
- ASTN2 | c.2596G>T p.V866L (on ENST00000313400 / NM_001365069.1; = p.V815L on NM_014010.5) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100527761; called by muse, mutect2
- BTN1A1 | c.973G>T p.V325F | Missense Mutation (SNP) | VAF 56/1106 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV55066380, COSV99764406; called by muse, mutect2
- C14orf39 | c.1681C>G p.Q561E | Missense Mutation (SNP) | VAF 120/299 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV58780397, COSV58783316; called by muse, mutect2, varscan2
- CADM1 | c.740T>A p.I247N | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59006057, COSV59024072; called by muse, mutect2, varscan2
- CCDC146 | c.1413A>C p.Q471H | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV53545849; called by muse, mutect2, varscan2
- CDH17 | c.1451G>T p.S484I | Missense Mutation (SNP) | VAF 112/382 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50326645; called by muse, mutect2, varscan2
- CISH | c.429C>A p.N143K (on ENST00000348721 / NM_145071.4; = p.N160K on NM_013324.6) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); catalogued as COSV100811766; called by muse, mutect2
- DLG5 | c.1202A>T p.Q401L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV100967510; called by muse, mutect2, varscan2
- DOC2A | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58750920; called by muse, mutect2, varscan2
- ENPP2 | c.2362C>A p.P788T (on ENST00000075322 / NM_001040092.3; = p.P840T on NM_006209.5) | Missense Mutation (SNP) | VAF 43/338 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.481); catalogued as COSV50011636; called by muse, mutect2, varscan2
- FLNB | c.3915G>C p.E1305D | Missense Mutation (SNP) | VAF 106/298 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV55874221; called by muse, mutect2
- GAB2 | c.1558G>A p.D520N (on ENST00000361507 / NM_080491.3; = p.D482N on NM_012296.3) | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV60866751; called by muse, mutect2, varscan2
- GJB5 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as rs1039036128, COSV58355725; called by muse, mutect2, varscan2
- GORASP1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs750666409, COSV100073156, COSV57183916; called by muse, mutect2, varscan2
- GRK5 | c.1189G>T p.V397L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); catalogued as COSV100963078; called by muse, varscan2
- GTF2IRD2B | c.2368A>G p.K790E | Missense Mutation (SNP) | VAF 87/383 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57030497; called by muse, mutect2, varscan2
- HCN4 | c.1600G>A p.V534M | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56082283; called by muse, mutect2, varscan2
- IFT81 | c.920C>G p.S307C | Missense Mutation (SNP) | VAF 80/404 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV54361419; called by muse, mutect2, varscan2
- KALRN | c.7492C>G p.P2498A (on ENST00000360013 / NM_001024660.4; = p.P801A on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/310 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52252434; called by muse, mutect2, varscan2
- KIF5A | c.1000A>T p.N334Y | Missense Mutation (SNP) | VAF 16/535 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99673021; called by muse, mutect2
- KMO | c.814C>A p.L272I | Missense Mutation (SNP) | VAF 91/144 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.167); catalogued as COSV63805828; called by muse, mutect2, varscan2
- LCT | c.2146G>C p.V716L | Missense Mutation (SNP) | VAF 83/318 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV51546140, COSV51551994; called by muse, mutect2, varscan2
- LGR6 | c.2041C>A p.P681T (on ENST00000367278 / NM_001017403.1; = p.P629T on NM_021636.3) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.326); catalogued as COSV55166520, COSV99706988; called by muse, mutect2, varscan2
- LHCGR | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 134/351 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54294651; called by muse, mutect2, varscan2
- LRP1B | c.6473G>A p.C2158Y | Missense Mutation (SNP) | VAF 52/370 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67199729; called by muse, mutect2, varscan2
- MPZ | c.587C>G p.A196G | Missense Mutation (SNP) | VAF 124/433 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.79); catalogued as COSV60667967; called by muse, mutect2, varscan2
- MROH2B | c.2348T>C p.I783T | Missense Mutation (SNP) | VAF 111/199 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as COSV68182401; called by muse, mutect2, varscan2
- MS4A15 | c.180G>T p.L60F | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV61961006; called by muse, mutect2, varscan2
- MUC16 | c.18472C>A p.Q6158K | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV67454619; called by muse, mutect2, varscan2
- MUC16 | c.15309G>C p.K5103N | Missense Mutation (SNP) | VAF 109/511 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV67454625; called by muse, mutect2, varscan2
- NCF2 | c.1322A>C p.E441A | Missense Mutation (SNP) | VAF 135/444 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV62316317; called by muse, mutect2, varscan2
- NCF2 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 134/442 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs759940920, COSV62314830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRC4 | c.1495G>T p.V499L | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV61591930; called by muse, mutect2, varscan2
- NUP160 | c.868G>T p.V290F | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV101021489; called by muse, mutect2
- OAZ3 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100162540; called by muse, mutect2
- OR4D10 | c.227T>C p.I76T | Missense Mutation (SNP) | VAF 200/436 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV73259991; called by muse, mutect2, varscan2
- OR5D16 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 86/228 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as rs375193534, COSV101004143, COSV65721854; called by muse, mutect2, varscan2
- OR6C75 | c.398T>A p.I133N | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as COSV58551689; called by muse, mutect2, varscan2
- OTOR | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 89/140 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55721808, COSV55722275; called by muse, mutect2, varscan2
- PAMR1 | c.447C>G p.H149Q | Missense Mutation (SNP) | VAF 91/778 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as COSV53510870; called by muse, mutect2, varscan2
- PI4K2B | c.1143G>C p.L381F | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV53510735, COSV53511694; called by muse, mutect2, varscan2
- PIK3CB | c.1536T>G p.I512M | Missense Mutation (SNP) | VAF 106/262 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV56684335; called by muse, mutect2, varscan2
- PPFIA4 | c.2922G>A p.M974I (on ENST00000447715; = p.M975I on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV55310965, COSV55313125; called by muse, mutect2, varscan2
- RELN | c.4437T>G p.D1479E | Missense Mutation (SNP) | VAF 110/219 reads (50%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.815); catalogued as COSV58992600; called by muse, mutect2, varscan2
- RGS22 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV62659387; called by muse, mutect2, varscan2
- RPL23A | c.399G>C p.E133D | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV52643906; called by muse, mutect2, varscan2
- RTP1 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV100398724; called by muse, mutect2
- SEC14L3 | c.736A>G p.T246A | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV53178618; called by muse, mutect2, varscan2
- SHLD2 | c.1931C>G p.A644G | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV53953688; called by muse, mutect2, varscan2
- SLC26A3 | c.1839A>G p.I613M | Missense Mutation (SNP) | VAF 105/238 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV60639427; called by muse, mutect2, varscan2
- SLC6A6 | c.1705G>C p.E569Q | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV62648382; called by muse, mutect2, varscan2
- SLC7A1 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101060212; called by muse, mutect2
- SLCO1C1 | c.1324C>G p.L442V | Missense Mutation (SNP) | VAF 111/166 reads (67%) | SIFT tolerated (0.43); PolyPhen benign (0.246); catalogued as COSV56870307; called by muse, mutect2, varscan2
- TAF1L | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 22/498 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as COSV99644765; called by muse, mutect2
- TCP11 | c.1462A>C p.T488P (on ENST00000512012; = p.T426P on NM_018679.5) | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV55132709; called by muse, mutect2, varscan2
- TIMM44 | c.1192G>A p.V398M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.214); catalogued as COSV99564086; called by muse, mutect2, varscan2
- TNRC6A | c.3182G>T p.G1061V | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV59362485; called by muse, mutect2, varscan2
- TRAIP | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58913674, COSV58915461; called by muse, mutect2, varscan2
- TRAPPC12 | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 59/301 reads (20%) | catalogued as COSV100160563; called by muse, mutect2, varscan2
- TYR | c.950A>C p.D317A | Missense Mutation (SNP) | VAF 142/360 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV54472501; called by muse, varscan2
- UBC | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 118/248 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as rs766054093, COSV60058846; called by muse, mutect2, varscan2
- USP21 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 66/105 reads (63%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.221); catalogued as COSV57087487; called by muse, mutect2, varscan2
- USP7 | c.2734C>G p.P912A | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.554); catalogued as COSV100784196; called by muse, mutect2
- VPS33A | c.1489G>C p.V497L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV99931379; called by muse, mutect2, varscan2
- XDH | c.2401G>C p.G801R | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101052206; called by muse, mutect2
- XG | c.416T>C p.M139T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV66985480; called by muse, mutect2, varscan2
- ZKSCAN4 | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV101043440; called by muse, mutect2, varscan2
- ZNF292 | c.8118G>T p.M2706I | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV60537092; called by muse, mutect2, varscan2
- ZNF354B | c.647G>A p.C216Y | Missense Mutation (SNP) | VAF 152/379 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59365513; called by muse, mutect2, varscan2
- ZNF564 | c.1165G>C p.G389R | Missense Mutation (SNP) | VAF 24/421 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as COSV100213133; called by muse, mutect2
- ZNF609 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs369004534, COSV58581553; called by muse, mutect2, varscan2
- ABCA9 | c.3304_3321+16del p.X1102_splice | Splice Site (DEL) | VAF 40/176 reads (23%) | called by mutect2, pindel, varscan2
- C3 | c.2630C>A p.T877N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2
- COL24A1 | c.2025_2032del p.P676Vfs*5 | Frame Shift Del (DEL) | VAF 37/128 reads (29%) | called by mutect2, pindel, varscan2
- CRYBG1 | c.4107_4132del p.A1370Ifs*10 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- CYP4F2 | c.799_820del p.T267Gfs*31 | Frame Shift Del (DEL) | VAF 46/186 reads (25%) | called by mutect2, pindel, varscan2
- DYSF | c.4804_4816del p.Y1602Pfs*2 | Frame Shift Del (DEL) | VAF 87/374 reads (23%) | called by mutect2, pindel, varscan2
- KAT8 | c.1344dup p.K449Qfs*39 | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | called by mutect2, pindel
- KIF20B | c.2648_2670del p.N883Ifs*5 (on ENST00000371728 / NM_001284259.2; = p.N843Ifs*5 on NM_016195.4) | Frame Shift Del (DEL) | VAF 34/148 reads (23%) | called by mutect2, pindel, varscan2
- MME | c.1416+4_1416+45del p.X472_splice | Splice Site (DEL) | VAF 38/91 reads (42%) | called by mutect2, pindel
- PAMR1 | c.1144_1170del p.Q382_K390del (on ENST00000619888 / NM_001001991.3; = p.Q399_K407del on NM_015430.4) | In Frame Del (DEL) | VAF 60/474 reads (13%) | called by mutect2, pindel
- RPS6 | c.13_15del p.I5del | In Frame Del (DEL) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- TEX14 | c.3869_3914del p.S1290Yfs*15 (on ENST00000240361 / NM_001201457.2; = p.S1244Yfs*15 on NM_031272.5) | Frame Shift Del (DEL) | VAF 26/180 reads (14%) | called by mutect2, pindel
- ARFGEF1 | c.1773A>G p.Q591= | Silent (SNP) | VAF 124/399 reads (31%) | catalogued as COSV51605088; called by muse, mutect2, varscan2
- ARHGAP30 | c.858C>T p.V286= | Silent (SNP) | VAF 107/140 reads (76%) | catalogued as COSV63515413; called by muse, mutect2, varscan2
- CREB3L3 | c.405A>G p.T135= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV50178943; called by muse, mutect2, varscan2
- DNAH9 | c.7512C>T p.N2504= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs199937308, COSV52340966; called by muse, mutect2, varscan2
- DYNC2LI1 | c.132G>A p.K44= | Silent (SNP) | VAF 92/227 reads (41%) | catalogued as COSV53182756; called by muse, mutect2, varscan2
- INTS14 | c.66C>T p.S22= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs369672173; called by muse, mutect2, varscan2
- IQSEC2 | c.1212G>A p.A404= (on ENST00000642864 / NM_001111125.3; = p.A199= on NM_015075.2) | Silent (SNP) | VAF 40/62 reads (65%) | catalogued as rs370611796, COSV64724421; called by muse, mutect2, varscan2
- KCND3 | c.1209T>C p.V403= | Silent (SNP) | VAF 92/213 reads (43%) | catalogued as COSV56177452; called by muse, mutect2, varscan2
- KLHL38 | c.1062C>T p.Y354= | Silent (SNP) | VAF 22/322 reads (7%) | catalogued as rs1354697970, COSV100384405; called by muse, mutect2
- LAS1L | c.1185G>C p.T395= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV56706447, COSV56706723; called by muse, mutect2, varscan2
- MSS51 | c.675G>A p.P225= | Silent (SNP) | VAF 65/172 reads (38%) | catalogued as rs1053776066, COSV55018846; called by muse, mutect2, varscan2
- NRXN2 | c.3987C>A p.P1329= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV55450151, COSV99632500; called by muse, mutect2, varscan2
- PCDHB12 | c.2031C>T p.A677= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV53394465; called by muse, mutect2
- PRAMEF15 | c.669G>A p.L223= | Silent (SNP) | VAF 56/530 reads (11%) | catalogued as rs1395401408; called by mutect2, varscan2
- PRG3 | c.195G>A p.K65= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV99755955; called by muse, mutect2, varscan2
- SAMD9L | c.3930G>A p.L1310= | Silent (SNP) | VAF 83/377 reads (22%) | catalogued as COSV59080471; called by muse, mutect2, varscan2
- SLC16A4 | c.471G>A p.L157= | Silent (SNP) | VAF 59/329 reads (18%) | catalogued as COSV63916145; called by muse, mutect2, varscan2
- VWA3B | c.1338A>C p.A446= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as COSV68241797; called by muse, mutect2, varscan2
- CDKN2A | c.150+73G>C | Intron (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- GRK5 | c.148+7187C>G | Intron (SNP) | VAF 23/77 reads (30%) | catalogued as COSV67309596; called by muse, mutect2, varscan2
- NCAM1 | c.1826-5570G>T | Intron (SNP) | VAF 13/374 reads (3%) | catalogued as COSV100377821; called by muse, mutect2
- PDE4DIP | c.637-7225G>A | Intron (SNP) | VAF 8/113 reads (7%) | catalogued as COSV100519476; called by muse, mutect2
